Surgical pathology report (de-identified scan), TCGA case TCGA-49-6744, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Johns Hopkins, specimen TCGA-49-6744-01A (Primary Tumor).

[page 1 of 2]
SP-CONS -

SURG PATH REPORT

COLLECTION DATE/TIME:

1st Specimen collected on

Accessioned on

FINAL DIAGNOSIS ----- Primary Pathologist:

Other Pathologist:

1. STATION (RESECTION): THREE LYMPH NODE AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

2. L11 LYMPH NODE (RESECTION): METASTATIC ADENOCARCINOMA IN ONE OF TWO LYMPH NODES (1/2).

3. STATION 6 LYMPH NODE (RESECTION): TWO LYMPH NODE AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

4. LEFT UPPER LOBE LUNG (LOBECTOMY0:
SPECIMEN TYPE:
Lobectomy.

TUMOR SITE:
Left.

HISTOLOGIC TYPE:
Adenocarcinoma, mixed acinar (dominant component) & bronchioloalveolar types.

TUMOR SIZE:
Greatest dimension 3.5cm.

LOCATION, SIZE, AND HISTOLOGIC TYPE OF
SEPARATE TUMOR NODULES, IF ANY:
none identified.

HISTOLOGIC GRADE:
G2-G3: Moderately to Poorly differentiated (the poorly differentiated component represents less than 5% of the tumor).

LYMPH NODES:
Metastatic carcinoma in 3 of 18 lymph nodes. (see part 1-6).

DIRECT EXTENSION OF TUMOR:
none identified

EXTENT OF INVASION (7th Edition, AJCC):
PRIMARY TUMOR: pT2a: Tumor more than 3 cm but 5 cm or less.

REGIONAL LYMPH NODES:
pN1: Metastasis in ipsilateral peribronchial lymph nodes.

MARGINS:
margins uninvolved by invasive carcinoma.

VENOUS/ARTERIAL (LARGE VESSEL) INVASION:
Indeterminate. There are obliterated vessels within the tumor but no carcinoma is seen in the lumina.

LYMPHATIC (SMALL VESSEL) INVASION:
Indeterminate.

ADDITIONAL PATHOLOGIC FINDINGS:
Emphysematous changes with subpleural bulla formation.

NOTE: EGPR & KRAS ordered on block 4E. Results will be reported in an addendum.

[page 2 of 2]
[REDACTED]

5. STATION 5 LYMPH NODE (RESECTION): ONE LYMPH NODE AND ASSOCIATED
FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

6. STATION 7 LYMPH NODE (RESECTION): ONE LYMPH NODE AND ASSOCIATED
FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

ADDENDUM ----- Pathologist: [REDACTED]

KRAS MUTATION ANALYSIS:

BLOCK TESTED: [REDACTED]

RESULT: POSITIVE

NOTE: The assay detected a mutation in either codon 12 or 13 of the
KRAS gene. A copy of the complete report is available in [REDACTED]
[REDACTED] and is also on file in the [REDACTED]

[REDACTED] Based on these results, EGFR testing is not
needed.

See [REDACTED] for official report.

Reported by:
[REDACTED]
[REDACTED]

=====

[REDACTED]

Source: NCI Genomic Data Commons file 2ba9f778-54f3-4926-8fbc-25cab50e1363 (TCGA-49-6744.9A6D2CC6-3D78-42EC-B747-74BB6E96D22B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).